Gene-level copy-number profile of tumor specimen TCGA-04-1350-01A from TCGA case TCGA-04-1350, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 46.4 years (16,942 days).
Specimen TCGA-04-1350-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.9ee784ec-de14-4b73-b0eb-94f4ff4defcf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1350-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e45e88bd-f6c0-44a8-b5d5-e0c7cb4ba71d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,570; copy number 2: 22,290; copy number 3: 17,776; copy number 4: 13,687; copy number 5: 3,157; copy number 6: 238; copy number 7: 86; copy number 9: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-04-1350-01): tumor purity 0.99, ploidy 3.04, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,490 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:32,825,359–36,355,114, 33 genes, copy number 5: LINC00486, LINC00486, Y_RNA, LTBP1, H2ACP2, AC019127.1, RNA5SP91, RNA5SP92, MIR4430, RASGRP3, RASGRP3-AS1, FAM98A, AC017050.1, ATP6V0E1P3, HNRNPA1P61, LINC01320, MYADML, SLC25A5P2, LINC01318, AC008170.1, AC073218.1, AC012593.2, AC012593.1, RN7SL602P, AC019064.1, SMIM7P1, AC013442.1, MIR548AD, RNU6-1117P, AC083939.1, MRPL50P1, RPL21P36, CRIM1-DT.
- chr2:79,185,231–80,648,861, 1 gene, copy number 5 (within-gene range 4–5): CTNNA2.
- chr2:79,866,495–84,040,720, 30 genes, copy number 5: MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1.
- chr2:102,311,502–104,722,966, 38 genes, copy number 5: IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9, TMEM182, LINC01796, LINC01935, AC108051.1, AC073987.1, AC010881.1, AC011593.1, CRLF3P1, AC018880.1, CAPZBP1, AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1, AHCYP3, AC068535.1, LINC01831, AC068535.2, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2.
- chr2:113,705,011–115,940,291, 21 genes, copy number 5: SLC35F5, MIR4782, AC104653.2, AC104653.1, AC110769.2, ACTR3, AC110769.3, LINC01191, AC110769.1, U3, AC010982.2, AC010982.1, SEPHS1P7, RNU2-41P, DPP10, DPP10-AS3, DPP10-AS2, AC093610.1, DPP10-AS1, RPSAP23, AC016721.1.
- chr2:220,776,818–221,650,218, 9 genes, copy number 5: AC093843.1, AC093843.2, AC011233.1, AC011233.2, EPHA4, TMEM256P2, AC079834.1, RPL23P5, AC068489.1.
- chr3:143,265,222–143,848,485, 1 gene, copy number 5 (within-gene range 4–5): SLC9A9.
- chr3:143,342,246–146,544,856, 24 genes, copy number 5 (within-gene range 4–5): SLC9A9-AS1, SLC9A9-AS2, GAPDHP47, ST13P15, AC073358.1, AC107421.1, DIPK2A, RNA5SP144, AC011592.1, LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1.
- chr3:187,217,282–192,917,856, 63 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:2,184,710–4,147,429, 18 genes, copy number 5: Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063.
- chr5:17,511,833–30,365,684, 139 genes, copy number 5 (broad region; genes not listed).
- chr5:44,300,247–45,895,970, 15 genes, copy number 5: FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr8:2,726,956–6,257,537, 26 genes, copy number 5: AC246817.1, AC115485.1, AC023296.1, CSMD1, AC026991.1, AC026991.2, RNA5SP251, AC027251.1, AC010941.1, AC022068.1, PAICSP4, AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2, AC087369.1, AC087369.2, RN7SKP159, AC079054.1, AC009435.1.
- chr8:35,862,123–37,758,422, 33 genes, copy number 6: AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2.
- chr8:131,904,093–132,013,642, 1 gene, copy number 6: EFR3A.
- chr10:36,089,086–38,783,108, 58 genes, copy number 5: AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr11:2,129,112–2,397,397, 17 genes, copy number 7: IGF2, AC132217.2, AC132217.1, INS-IGF2, MIR483, IGF2-AS, INS, TH, MIR4686, ASCL2, C11orf21, TSPAN32, RNU6-878P, CD81-AS1, RPL26P30, Y_RNA, CD81.
- chr11:48,880,111–55,686,160, 96 genes, copy number 5 (broad region; genes not listed).
- chr11:69,467,598–135,075,908, 1,393 genes, copy number 5–9 (broad region; genes not listed).
- chr14:52,552,836–106,875,071, 1,406 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:11,925,075–11,979,290, 1 gene, copy number 7 (within-gene range 3–7): AC008770.2.
- chr19:11,965,037–12,758,458, 67 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 149. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
